Gene-level copy-number profile of tumor specimen C3N-02950-02 from CPTAC case C3N-02950, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G2; Age at diagnosis: 72.6 years (26,507 days).
Specimen C3N-02950-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 86964251-602f-488c-818b-50cd8e79daf3.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-02950-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,228 have no estimate.
https://portal.gdc.cancer.gov/files/a679ebf8-b317-4b91-b8da-56cd29584660

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 24; copy number 1: 57; copy number 2: 10,462; copy number 3: 12,426; copy number 4: 33,075; copy number 5: 1,364; copy number 6: 608; copy number 7: 116; copy number 8: 29; copy number 9: 101; copy number 10: 118; copy number 11: 15.

Homozygous deletions (total copy number 0; autosomes only): 24 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,802,636–23,438,700, 20 genes: MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1.
- chr9:61,642,383–61,642,494, 1 gene: Y_RNA.
- chr19:43,192,702–43,269,530, 3 genes: PSG4, CEACAMP10, PSG9.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 234 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr17:70,312,831–73,092,712, 23 genes, copy number 9–11 (within-gene range 7–11): AC011990.1, AC005771.1, AC007423.1, AC005181.1, CASC17, RNU7-155P, AC118653.1, MYL6P5, ROCR, LINC01152, AC007461.1, SOX9-AS1, LINC02097, SOX9, LINC00511, LINC02003, AC007639.1, RPL32P33, AC080037.2, SLC39A11, RN7SKP180, AC080037.1, AC011120.1.
- chr17:74,466,399–75,432,087, 57 genes, copy number 9: CD300A, CD300LB, CD300C, AC079325.1, CD300H, CD300LD, C17orf77, AC064805.1, CD300E, AC064805.2, RAB37, CD300LF, AC016888.1, MIR3615, SLC9A3R1, NAT9, TMEM104, GRIN2C, FDXR, FADS6, USH1G, OTOP2, OTOP3, HID1, HID1-AS1, CDR2L, MRPL58, RNU6-362P, KCTD2, ATP5PD, RN7SL573P, AC111186.1, TRIM80P, SLC16A5, Y_RNA, ARMC7, NT5C, AC022211.4, JPT1, AC022211.3, AC022211.1, Y_RNA, SUMO2, NUP85, GGA3, MRPS7, MIF4GD, AC022211.2, SLC25A19, GRB2, AC011933.1, AC011933.4, AC011933.2, AC011933.3, MIR3678, RNU6-938P, Y_RNA.
- chr17:77,257,737–78,278,492, 36 genes, copy number 9: SEPTIN9-DT, AC068594.1, SEPTIN9, AC111182.1, AC111182.2, MIR4316, Y_RNA, AC111170.3, AC111170.2, AC111170.1, AC021683.3, AC021683.2, AC021683.6, AC021683.1, AC021683.4, LINC01987, LINC01973, RNU1-80P, TNRC6C, AC015804.1, UBE2V2P2, RNU6-625P, TMC6, TMC8, C17orf99, EIF5AP2, SYNGR2, TK1, AFMID, AC087645.1, BIRC5, TMEM235, AC087645.4, THA1P, AC087645.3, LINC01993.
- chr20:62,122,461–64,049,639, 118 genes, copy number 10 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 57. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
